Somatic mutation profile of tumor specimen TCGA-CN-5366-01A (aliquot TCGA-CN-5366-01A-01D-1434-08) from TCGA case TCGA-CN-5366, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 51.8 years (18,904 days).
Specimen TCGA-CN-5366-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f30949c5-0ed1-49a7-b42a-f561782c9e49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5366-10A (Blood Derived Normal), aliquot TCGA-CN-5366-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c402feb6-b31f-4316-8354-c13ad5ac1ba9

The open-access MAF lists 103 somatic variants for this specimen: 77 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 23, Nonsense Mutation 7, Frame Shift Ins 4, Splice Site 2, Frame Shift Del 1, In Frame Del 1, Splice Region 1, RNA 1, Intron 1, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.517G>A p.V173M | Missense Mutation (SNP) | VAF 41/116 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALX1 | c.623A>C p.D208A | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100374349; called by muse, mutect2, varscan2
- ANK3 | c.4354G>C p.E1452Q (on ENST00000280772 / NM_001320874.2; = p.E577Q on NM_001149.3) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV99779088, COSV99779334; called by muse, mutect2, varscan2
- BCL9 | c.3575T>C p.L1192P | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99324851; called by muse, mutect2
- BRCA2 | c.8652T>A p.Y2884* | Nonsense Mutation (SNP) | VAF 20/96 reads (21%) | catalogued as COSV66457292; called by muse, varscan2
- C8orf34 | c.1310A>T p.K437I | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100297897; called by muse, mutect2, varscan2
- CD163L1 | c.3355G>A p.G1119S | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as rs149805278; called by muse, mutect2, varscan2
- CFAP94 | c.280C>T p.Q94* (on ENST00000320267 / NM_001352064.2; = p.Q100* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as COSV100209159; called by muse, mutect2, varscan2
- CHST13 | c.180+2T>C p.X60_splice | Splice Site (SNP) | VAF 25/119 reads (21%) | catalogued as COSV60042656; called by muse, mutect2, varscan2
- CNKSR2 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV54260732; called by muse, mutect2, varscan2
- COBLL1 | c.3128A>T p.N1043I (on ENST00000392717; = p.N1005I on NM_014900.5) | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV52071257; called by muse, mutect2, varscan2
- CST4 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 32/301 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745606281, COSV54149132; called by muse, mutect2, varscan2
- DDX3Y | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV60177066; called by muse, mutect2, varscan2
- DNM3 | c.370G>T p.V124F | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV100797987; called by muse, mutect2
- DPEP2 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 34/164 reads (21%) | catalogued as COSV52054604, COSV52055124; called by muse, mutect2, varscan2
- EDRF1 | c.508C>T p.Q170* | Nonsense Mutation (SNP) | VAF 22/158 reads (14%) | catalogued as COSV61764982; called by muse, mutect2, varscan2
- ESYT2 | c.1060A>G p.I354V (on ENST00000613624; = p.I278V on NM_020728.3) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs535480730, COSV51752346; called by muse, mutect2, varscan2
- FAT2 | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55824008; called by muse, mutect2, varscan2
- FBXO3 | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV99682149; called by muse, mutect2
- FBXW7 | c.1627A>G p.R543G (on ENST00000281708 / NM_001349798.2; = p.R463G on NM_018315.5) | Missense Mutation (SNP) | VAF 41/211 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV55918713; called by muse, mutect2, varscan2
- FPR2 | c.621delinsTT p.I208Yfs*4 | Frame Shift Ins (INS) | VAF 30/152 reads (20%) | catalogued as COSV60674412; called by mutect2*, pindel, varscan2*
- FYB1 | c.1003G>C p.G335R | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV100685207; called by muse, mutect2
- GRM8 | c.1159C>T p.L387= | Splice Region (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100281891, COSV58832977; called by muse, mutect2, varscan2
- GTF2A1 | c.199C>G p.L67V | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV53337681; called by muse, mutect2, varscan2
- GTF2B | c.416A>G p.N139S | Missense Mutation (SNP) | VAF 27/216 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV65137340; called by muse, mutect2, varscan2
- HAUS6 | c.1954C>A p.H652N | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.271); catalogued as rs1245731798, COSV100997802; called by muse, mutect2
- HDAC9 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1054512034, COSV101286646; called by muse, mutect2, varscan2
- HPS1 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 59/274 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.311); catalogued as COSV57267715; called by muse, mutect2, varscan2
- ITGA5 | c.2327A>T p.Q776L | Missense Mutation (SNP) | VAF 54/243 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.039); catalogued as COSV53219199; called by muse, mutect2, varscan2
- KCNG3 | c.786C>G p.I262M | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60149995; called by muse, mutect2, varscan2
- LDLRAD2 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100760750; called by muse, mutect2
- MAPK9 | c.428A>T p.H143L | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58123558; called by mutect2, varscan2
- MYH13 | c.5556G>T p.K1852N | Missense Mutation (SNP) | VAF 38/330 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52834672; called by muse, mutect2, varscan2
- MYO18A | c.5623C>T p.R1875W | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs769302948, COSV62869761; called by muse, mutect2, varscan2
- MYO18A | c.992C>T p.P331L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1257237132; called by muse, mutect2
- MYO9B | c.3748C>T p.R1250W | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs747809355, COSV101261475; called by muse, varscan2
- NDST3 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.981); catalogued as COSV56623083; called by muse, mutect2, varscan2
- NIN | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 58/405 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV55397199; called by muse, mutect2, varscan2
- NRK | c.1414C>T p.R472W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV54597186; called by muse, mutect2, varscan2
- OR51F1 | c.188G>C p.S63T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.938); catalogued as rs746797802, COSV100598720; called by muse, mutect2, varscan2
- OR52N4 | c.919A>T p.I307L | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57891743; called by muse, varscan2
- PCDHGA3 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as rs1392259698, COSV53981678; called by muse, mutect2, varscan2
- PDZRN3 | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs201195316, COSV99728788; called by muse, mutect2
- PIGK | c.998A>G p.D333G | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV63652129; called by muse, varscan2
- PLEKHM1 | c.2906C>G p.A969G | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV69599185; called by muse, mutect2, varscan2
- PPAT | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 38/189 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.199); catalogued as rs1274139617, COSV51705270; called by muse, mutect2, varscan2
- PSG4 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 46/448 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54937616; called by muse, mutect2, varscan2
- PTPRZ1 | c.5347A>G p.I1783V | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV66440887; called by muse, mutect2, varscan2
- RBAK | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 46/261 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV62331903; called by muse, mutect2, varscan2
- SETBP1 | c.3880G>C p.D1294H | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV56328491; called by muse, mutect2, varscan2
- SETD1A | c.2065C>T p.R689W | Missense Mutation (SNP) | VAF 53/234 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567353627, COSV52689838, COSV52690050; called by muse, mutect2, varscan2
- SIN3A | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 61/274 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV64583852; called by muse, mutect2, varscan2
- SLC6A17 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.322); catalogued as rs142242142; called by muse, mutect2, varscan2
- SLITRK3 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 51/260 reads (20%) | catalogued as COSV53848946, COSV99578768; called by muse, mutect2, varscan2
- SNRPN | c.587G>C p.R196T | Missense Mutation (SNP) | VAF 30/348 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV100578072; called by muse, mutect2
- STAB2 | c.2381G>A p.C794Y | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1566003429, COSV101185807; called by muse, mutect2, varscan2
- SYT6 | c.746G>A p.R249H (on ENST00000610222 / NM_001366225.1; = p.R164H on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs139165674, COSV101059648; called by muse, mutect2, varscan2
- TET2 | c.1763C>A p.S588* | Nonsense Mutation (SNP) | VAF 33/119 reads (28%) | catalogued as COSV54406059, COSV99482385; called by muse, mutect2, varscan2
- TFDP1 | c.230T>C p.V77A | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV64741252; called by muse, mutect2, varscan2
- TLR4 | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs756229233, COSV62923720; called by muse, mutect2, varscan2
- TMC4 | c.1718C>T p.S573F (on ENST00000617472 / NM_001145303.3; = p.S567F on NM_144686.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.015); catalogued as COSV55828741, COSV99713782; called by muse, mutect2, varscan2
- TMEM132E | c.2417G>A p.G806D (on ENST00000321639; = p.G896D on NM_001304438.2) | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1160314122, COSV58698661; called by muse, mutect2, varscan2
- TRIM58 | c.553G>C p.E185Q | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV100825011; called by muse, varscan2
- TXLNB | c.1966C>T p.R656* | Nonsense Mutation (SNP) | VAF 53/184 reads (29%) | catalogued as COSV64444717; called by muse, mutect2, varscan2
- UCP3 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV58368737; called by muse, mutect2
- USH2A | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56395876; called by muse, mutect2
- WDR35 | c.1903A>G p.I635V (on ENST00000345530 / NM_001006657.2; = p.I624V on NM_020779.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV99853039; called by muse, mutect2, varscan2
- ZFHX4 | c.99G>C p.E33D | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated, low confidence (0.81); PolyPhen probably damaging (0.99); catalogued as COSV50668993, COSV99260913; called by muse, mutect2, varscan2
- ZNF429 | c.740A>G p.H247R | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs779776849, COSV61917302; called by muse, mutect2, varscan2
- BCAR3 | c.2072_2073dup p.H692Cfs*20 | Frame Shift Ins (INS) | VAF 26/111 reads (23%) | called by mutect2, pindel, varscan2
- FAT1 | c.6224del p.N2075Mfs*32 | Frame Shift Del (DEL) | VAF 97/331 reads (29%) | called by mutect2, pindel, varscan2
- FPR2 | c.620dup p.I208Hfs*4 | Frame Shift Ins (INS) | VAF 40/132 reads (30%) | called by mutect2, varscan2
- IGKC | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- KIF9 | c.1290-6_1307del p.X430_splice | Splice Site (DEL) | VAF 32/156 reads (21%) | called by mutect2, pindel
- NPEPPS | c.2348_2350dup p.L783_G784insV | In Frame Ins (INS) | VAF 13/101 reads (13%) | called by mutect2, pindel, varscan2
- PHLPP2 | c.1458dup p.A487Cfs*33 | Frame Shift Ins (INS) | VAF 13/73 reads (18%) | called by mutect2, pindel, varscan2
- RASA1 | c.2395_2397del p.E799del | In Frame Del (DEL) | VAF 27/118 reads (23%) | called by mutect2, pindel, varscan2
- APOBEC3C | c.30G>A p.K10= | Silent (SNP) | VAF 19/190 reads (10%) | catalogued as COSV100815123; called by muse, mutect2, varscan2
- ATP8B2 | c.378T>A p.A126= (on ENST00000672630; = p.A93= on NM_001005855.2) | Silent (SNP) | VAF 35/132 reads (27%) | catalogued as COSV59247050; called by muse, mutect2, varscan2
- CATSPER1 | c.1008C>T p.H336= | Silent (SNP) | VAF 19/134 reads (14%) | catalogued as rs770226955, COSV56410115; called by muse, mutect2, varscan2
- COL12A1 | c.7107C>T p.S2369= | Silent (SNP) | VAF 41/181 reads (23%) | catalogued as rs754178898, COSV59400311; ClinVar: likely benign; called by muse, mutect2, varscan2
- COL1A2 | c.2526C>T p.F842= | Silent (SNP) | VAF 36/232 reads (16%) | catalogued as rs41317725; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- DNAH5 | c.3039C>T p.S1013= | Silent (SNP) | VAF 100/289 reads (35%) | catalogued as rs560267080, COSV54237491; called by muse, mutect2, varscan2
- GREB1 | c.5691G>A p.A1897= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs1479317236, COSV52182860, COSV52191001; called by muse, mutect2, varscan2
- IGHV7-81 | c.108A>C p.S36= | Silent (SNP) | VAF 83/304 reads (27%) | called by muse, mutect2, varscan2
- KIAA2013 | c.780C>T p.H260= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs775950416, COSV100927120; called by muse, mutect2, varscan2
- KRT72 | c.408C>T p.F136= | Silent (SNP) | VAF 28/142 reads (20%) | catalogued as rs1189472937, COSV53373663; called by muse, mutect2, varscan2
- LINS1 | c.324C>T p.T108= | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as rs777116466; called by muse, mutect2
- LRRC75B | c.619C>T p.L207= | Silent (SNP) | VAF 36/156 reads (23%) | catalogued as COSV99958753; called by muse, mutect2, varscan2
- LRRTM3 | c.1341G>C p.A447= | Silent (SNP) | VAF 19/149 reads (13%) | catalogued as COSV100791576, COSV100791943, COSV63668621; called by muse, mutect2, varscan2
- MFSD2A | c.1449G>A p.L483= (on ENST00000372809 / NM_001136493.3; = p.L470= on NM_032793.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 51/235 reads (22%) | catalogued as rs531676567, COSV65686084; called by muse, mutect2, varscan2
- NACA | c.450C>G p.V150= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV63271086; called by muse, mutect2, varscan2
- NADSYN1 | c.795C>T p.D265= | Silent (SNP) | VAF 25/396 reads (6%) | catalogued as rs370965046; called by muse, mutect2
- NDST4 | c.249C>T p.F83= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as COSV99996081; called by muse, mutect2, varscan2
- NEXMIF | c.2151C>G p.L717= | Silent (SNP) | VAF 5/118 reads (4%) | catalogued as COSV99280353; called by muse, mutect2
- PIGS | c.843G>T p.G281= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99256812; called by muse, mutect2, varscan2
- THBS2 | c.1857C>T p.C619= | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as rs976267969, COSV64680278; called by muse, mutect2, varscan2
- ZNF100 | c.1071C>T p.S357= | Silent (SNP) | VAF 20/214 reads (9%) | catalogued as COSV59747626, COSV99973903; called by muse, mutect2
- ZNF221 | c.1497C>A p.L499= | Silent (SNP) | VAF 35/169 reads (21%) | catalogued as COSV52110133; called by muse, mutect2, varscan2
- ZNF554 | c.1179A>T p.S393= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as COSV57886240; called by muse, mutect2, varscan2
- C8orf31 | n.717G>A | RNA (SNP) | VAF 22/171 reads (13%) | catalogued as rs764671402; called by muse, mutect2, varscan2
- DEF8 | c.-2G>A | 5'UTR (SNP) | VAF 21/115 reads (18%) | catalogued as COSV99240389; called by muse, mutect2, varscan2
- NEIL1 | c.719-116C>T | Intron (SNP) | VAF 14/127 reads (11%) | catalogued as rs909879190, COSV99145312; called by muse, mutect2, varscan2
